FM case AD1550 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Thymus.
https://portal.gdc.cancer.gov/cases/3dde1fd5-d09c-4a64-ada2-a02416b3dccd

Female, 34.7 years: Carcinoma, NOS (ICD-O-3 8010/3) of the thymus; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
